Somatic mutation profile of tumor specimen C3L-02118-02 (aliquot CPT0109300010_1) from CPTAC case C3L-02118, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.0 years (24,832 days).
Specimen C3L-02118-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25f29b22-a375-41a5-9153-26fb55b4a0a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02118-31 (Blood Derived Normal), aliquot CPT0109340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7990d861-6d02-4ef5-90dd-bc25ec6245dd

The open-access MAF lists 48 somatic variants for this specimen: 37 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 7, Intron 3, Nonsense Mutation 2, RNA 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 36/338 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 50/392 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD44 | c.2842G>A p.V948I | Missense Mutation (SNP) | VAF 23/355 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs572226231; called by muse, mutect2
- C6orf15 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 45/423 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1298952152; called by muse, mutect2, varscan2
- CDH10 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 19/357 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs140810299; called by muse, mutect2
- COL15A1 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV66646717; called by muse, mutect2
- DCAF4L1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1427420580; called by muse, mutect2
- ESPNL | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs751081371, COSV99615679; called by muse, mutect2, varscan2
- FIGNL2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1487475921; called by muse, mutect2, varscan2
- KIF15 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375650379; called by muse, mutect2, varscan2
- MORC2 | c.698C>T p.T233M (on ENST00000397641 / NM_001303256.3; = p.T171M on NM_014941.3) | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.894); catalogued as rs924468105; called by muse, mutect2, varscan2
- MROH9 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs766660390, COSV63012034; called by muse, mutect2, varscan2
- NACC1 | c.1217T>C p.F406S | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.705); catalogued as rs531044891; called by muse, mutect2, varscan2
- NMBR | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs745523807; called by muse, mutect2
- OR8K5 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376114385, COSV100537278; called by muse, mutect2
- PRAMEF20 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 44/788 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs1234445065; called by muse, mutect2
- SLITRK1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as rs765288417, COSV65676362; called by muse, mutect2, varscan2
- SPINT2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 36/870 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.154); catalogued as rs760976892; called by muse, mutect2
- SRCIN1 | c.2059C>T p.H687Y (on ENST00000621492; = p.H653Y on NM_025248.3) | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1323310056; called by muse, mutect2, varscan2
- SSX7 | c.402C>A p.N134K | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV53340677; called by muse, mutect2
- SYNJ2 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 41/279 reads (15%) | catalogued as rs201799213; called by muse, mutect2, varscan2
- TSSK4 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 31/460 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV104383239; called by muse, mutect2
- CDHR1 | c.348G>A p.L116= | Splice Region (SNP) | VAF 53/431 reads (12%) | called by muse, mutect2, varscan2
- DUSP6 | c.820_821insTC p.E274Vfs*7 | Frame Shift Ins (INS) | VAF 16/107 reads (15%) | called by mutect2, pindel*
- ESRRB | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 57/407 reads (14%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- FAM20B | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2
- IMPG2 | c.1730A>T p.K577I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRX2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- LEP | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRRN3 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MCRIP2 | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PANX2 | c.665T>C p.F222S | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.673); called by muse, mutect2
- POPDC2 | c.383A>G p.E128G | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, varscan2
- PRAMEF5 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 64/355 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SHROOM3 | c.5816A>G p.D1939G | Missense Mutation (SNP) | VAF 34/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TARS2 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZC3H12B | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- ADCY5 | c.3543C>T p.I1181= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs746474779, COSV59199681; called by muse, mutect2
- FAM214A | c.900A>G p.L300= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as rs200513144; called by muse, mutect2
- SLC6A15 | c.102T>C p.F34= | Silent (SNP) | VAF 37/287 reads (13%) | called by muse, mutect2, varscan2
- SND1 | c.276G>A p.G92= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as rs1341158474; called by muse, mutect2
- SOX30 | c.1263C>T p.S421= | Silent (SNP) | VAF 60/350 reads (17%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.1026G>A p.A342= | Silent (SNP) | VAF 42/460 reads (9%) | catalogued as rs776068574, COSV66164008; called by muse, mutect2
- WNT7B | c.324C>T p.Y108= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as rs375198790; called by muse, mutect2, varscan2
- ADAMTS2 | c.1629+1054C>A | Intron (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- MYH16 | n.4472G>A | RNA (SNP) | VAF 28/278 reads (10%) | catalogued as rs777991094; called by muse, mutect2
- NKAIN3 | c.472-55160G>A | Intron (SNP) | VAF 44/214 reads (21%) | catalogued as rs1270151755, COSV100132401; called by mutect2, varscan2
- RRM2B | c.48+98T>C | Intron (SNP) | VAF 69/515 reads (13%) | called by muse, mutect2, varscan2
